MMRF case MMRF_1886 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6cdab22e-1caa-46b2-ad50-ee4bb57a9cf8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.5 years (24,302 days); ISS stage: II; Days to last known disease status: 1,088 days (3.0 years); Days to last follow up: 1,088 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 143 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 143 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 477 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 547 days (1.5 years); Days to treatment end: 561 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,088.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1420 mg/dL; Immunoglobulin G 2.45 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 4.8 µg/mL; Lactate Dehydrogenase 5.92 µkat/L; Hemoglobin 4.84 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.05 mmol/L; Albumin 28 g/L; Total Protein 4.8 g/dL; Glucose 8.75 mmol/L.
- Day 94 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.437 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Hemoglobin 5.83 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 5.17 mmol/L.
- Day 177 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.998 mg/dL; Hemoglobin 7.38 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.
- Day 262 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.934 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.838 mg/dL; Hemoglobin 7.56 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 165 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.62 mmol/L.
- Day 373 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.995 mg/dL; Hemoglobin 7.75 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 160 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 430 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 6.14 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 1.09 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 181 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 542 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 224 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 8.09 mmol/L.
- Day 597 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 5.42 g/L; Immunoglobulin A 0.335 g/L; Immunoglobulin M 0.586 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 180 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 6.38 mmol/L.
- Day 689 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 6.44 g/L; Immunoglobulin A 0.362 g/L; Immunoglobulin M 0.644 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 6.93 mmol/L.
- Day 800 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Immunoglobulin G 7.52 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.7 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 154 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.11 mmol/L.
- Day 884 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.85 mg/dL; Immunoglobulin G 7.82 g/L; Immunoglobulin A 0.437 g/L; Immunoglobulin M 0.832 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 6.66 mmol/L.
- Day 1,010 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Immunoglobulin G 6.65 g/L; Immunoglobulin A 0.394 g/L; Immunoglobulin M 0.865 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 7.37 mmol/L.
- Day 1,080: Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 6.32 g/L; Immunoglobulin A 0.387 g/L; Immunoglobulin M 0.891 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 146 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.44 mmol/L.

Other clinical attributes
- Day -3: Weight: 89 kg; Height: 174 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1886_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1886_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
